Somatic mutation profile of tumor specimen MMRF_1760_1_BM_CD138pos (aliquot MMRF_1760_1_BM_CD138pos_T1_KHS5U_L12896) from MMRF case MMRF_1760, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 78.9 years (28,836 days).
Specimen MMRF_1760_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2fbdef4-8127-470b-8ba2-471faf3544ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1760_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1760_1_PB_WBC_C2_KHS5U_L12895; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92069e2d-fd09-4054-9a06-4a379b41d642

The open-access MAF lists 77 somatic variants for this specimen: 31 protein-altering or splice-affecting, 9 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, 3'UTR 20, Intron 9, Silent 9, 5'UTR 3, 3'Flank 2, 5'Flank 2, RNA 1, Splice Site 1, Frame Shift Ins 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 13/100 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.6725T>C p.L2242P | Missense Mutation (SNP) | VAF 87/189 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.526); catalogued as COSV67981643; called by muse, mutect2, varscan2
- ASB18 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.822); catalogued as rs970104910; called by mutect2, varscan2
- ASCC2 | c.1873G>A p.V625M | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs375464148; called by muse, mutect2
- CREBBP | c.2548C>T p.Q850* | Nonsense Mutation (SNP) | VAF 8/193 reads (4%) | catalogued as COSV52135450; called by muse, mutect2
- DEDD2 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs750217130, COSV60143245; called by muse, mutect2, varscan2
- FAM186A | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs945697985; called by muse, mutect2, varscan2
- FBN1 | c.2294A>T p.D765V | Missense Mutation (SNP) | VAF 98/201 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as CD093624; called by muse, mutect2, varscan2
- FERMT2 | c.1348G>A p.G450S | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV104419941, COSV58409801; called by muse, mutect2, varscan2
- GPR155 | c.1429G>T p.V477L | Missense Mutation (SNP) | VAF 58/254 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140860447; called by muse, mutect2, varscan2
- IGHV1-69 | c.341A>G p.Y114C | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376711593; called by muse, mutect2, varscan2
- IGHV2-70 | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as rs557763852; called by muse, varscan2
- LUZP1 | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 65/144 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs760639391; called by muse, mutect2, varscan2
- MAF | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58154320; called by muse, mutect2, varscan2
- SLC28A3 | c.1630G>A p.V544M | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.811); catalogued as rs1403165279; called by muse, mutect2
- SOHLH1 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 98/199 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372765282; called by muse, mutect2
- ZNF517 | c.871T>A p.C291S | Missense Mutation (SNP) | VAF 102/191 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753252961; called by muse, mutect2, varscan2
- FOLH1B | n.1506G>C | Splice Region (SNP) | VAF 60/147 reads (41%) | called by muse, mutect2, varscan2
- GDF5 | c.503C>T p.T168I | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- IGHV1-69D | c.341A>G p.Y114C | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIAA0753 | c.2410C>T p.P804S | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- MUC2 | c.539A>T p.E180V | Missense Mutation (SNP) | VAF 92/209 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- PHACTR4 | c.1318A>G p.R440G (on ENST00000373839 / NM_001350159.2; = p.R450G on NM_023923.4) | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PITRM1 | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.041); called by muse, mutect2
- PTGS2 | c.257A>G p.N86S | Missense Mutation (SNP) | VAF 70/146 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPRD1B | c.698C>G p.A233G | Missense Mutation (SNP) | VAF 89/197 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TAX1BP1 | c.2086-1G>A p.X696_splice | Splice Site (SNP) | VAF 47/108 reads (44%) | called by muse, mutect2, varscan2
- TRIM16L | c.178del p.S60Afs*26 | Frame Shift Del (DEL) | VAF 48/148 reads (32%) | called by mutect2, pindel, varscan2
- ZBED8 | c.1718C>T p.S573L | Missense Mutation (SNP) | VAF 198/401 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- ZEB1 | c.777_778dup p.R260Kfs*29 | Frame Shift Ins (INS) | VAF 11/58 reads (19%) | called by mutect2, pindel, varscan2
- ZNF687 | c.2206C>A p.P736T | Missense Mutation (SNP) | VAF 47/576 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNA2 | c.2754A>G p.K918= | Silent (SNP) | VAF 134/304 reads (44%) | called by muse, mutect2, varscan2
- FICD | c.351G>A p.K117= | Silent (SNP) | VAF 275/545 reads (50%) | called by muse, mutect2, varscan2
- HDGFL1 | c.321G>A p.P107= | Silent (SNP) | VAF 55/104 reads (53%) | catalogued as rs1288711494, COSV57753233; called by muse, mutect2, varscan2
- IGLL5 | c.79C>T p.L27= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as rs777349722, COSV73249535, COSV73250343, COSV73250409; called by muse, mutect2, varscan2
- MYO7B | c.621C>T p.N207= | Silent (SNP) | VAF 144/313 reads (46%) | catalogued as rs745638930; called by muse, mutect2, varscan2
- OR8B3 | c.111C>T p.V37= | Silent (SNP) | VAF 31/271 reads (11%) | called by muse, mutect2, varscan2
- SCART1 | c.2100G>A p.K700= | Silent (SNP) | VAF 16/94 reads (17%) | called by muse, mutect2, varscan2
- SECISBP2 | c.2163G>A p.Q721= | Silent (SNP) | VAF 14/143 reads (10%) | catalogued as rs887270868; called by muse, mutect2, varscan2
- TMEM39A | c.306T>G p.P102= | Silent (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- AC112695.1 | n.527T>C | RNA (SNP) | VAF 57/118 reads (48%) | called by muse, mutect2, varscan2
- ARMC1 | c.*220T>C | 3'UTR (SNP) | VAF 17/99 reads (17%) | called by muse, mutect2, varscan2
- BCL11A | c.-122C>T | 5'UTR (SNP) | VAF 98/214 reads (46%) | catalogued as rs1210659982; called by muse, varscan2
- CLEC7A | c.492+153C>T | Intron (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2
- COL12A1 | c.*1049T>C | 3'UTR (SNP) | VAF 38/86 reads (44%) | catalogued as rs970345006; called by muse, varscan2
- CPNE6 | c.499-49T>C | Intron (SNP) | VAF 53/201 reads (26%) | catalogued as rs1221881868; called by muse, mutect2, varscan2
- CYTH4 | c.353+72A>T | Intron (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2
- DELE1 | chr5:141941962 del CG | 3'Flank (DEL) | VAF 4/30 reads (13%) | called by pindel, varscan2
- DNAJC6 | c.*2299A>C | 3'UTR (SNP) | VAF 33/79 reads (42%) | called by muse, mutect2, varscan2
- FAM124B | c.*321A>T | 3'UTR (SNP) | VAF 35/80 reads (44%) | called by muse, mutect2, varscan2
- FAM20C | c.1445+70G>A | Intron (SNP) | VAF 29/98 reads (30%) | catalogued as rs374603721; called by muse, mutect2, varscan2
- GXYLT1 | c.*2916T>A | 3'UTR (SNP) | VAF 44/97 reads (45%) | called by muse, mutect2, varscan2
- HIPK1 | c.*2851G>A | 3'UTR (SNP) | VAF 41/144 reads (28%) | called by muse, mutect2, varscan2
- ID2 | c.-260C>A | 5'UTR (SNP) | VAF 43/195 reads (22%) | called by muse, mutect2, varscan2
- KRBOX4 | c.*69T>G | 3'UTR (SNP) | VAF 189/222 reads (85%) | catalogued as rs1292720172; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851153 C>T | 5'Flank (SNP) | VAF 135/296 reads (46%) | called by muse, mutect2, varscan2
- NCOA1 | c.*681A>T | 3'UTR (SNP) | VAF 14/244 reads (6%) | called by muse, mutect2
- PCGF1 | chr2:74504116 A>G | 3'Flank (SNP) | VAF 128/270 reads (47%) | called by muse, varscan2
- PHACTR1 | c.1392-36T>C | Intron (SNP) | VAF 118/251 reads (47%) | called by muse, mutect2, varscan2
- PHYHIPL | c.*679T>A | 3'UTR (SNP) | VAF 11/95 reads (12%) | called by muse, mutect2, varscan2
- PIK3C3 | c.*2509G>C | 3'UTR (SNP) | VAF 25/44 reads (57%) | called by muse, mutect2, varscan2
- PRPF40A | c.*88T>G | 3'UTR (SNP) | VAF 47/95 reads (49%) | called by muse, mutect2, varscan2
- PTPRG | c.*2368C>T | 3'UTR (SNP) | VAF 37/100 reads (37%) | catalogued as rs188149134; called by muse, mutect2, varscan2
- ROR1 | c.1174+725_1174+726insG | Intron (INS) | VAF 14/154 reads (9%) | called by mutect2, pindel
- RPL30 | c.-32-46T>A | Intron (SNP) | VAF 308/617 reads (50%) | called by muse, mutect2, varscan2
- SBSPON | c.*1400T>A | 3'UTR (SNP) | VAF 8/85 reads (9%) | called by muse, mutect2
- SLCO4C1 | c.*1379T>G | 3'UTR (SNP) | VAF 113/243 reads (47%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.*189T>G | 3'UTR (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- THAP5 | c.-51G>A | 5'UTR (SNP) | VAF 69/127 reads (54%) | called by muse, mutect2, varscan2
- TLCD4 | c.*3369T>G | 3'UTR (SNP) | VAF 58/114 reads (51%) | called by muse, mutect2, varscan2
- TLN2 | c.*2069T>C | 3'UTR (SNP) | VAF 52/123 reads (42%) | called by muse, mutect2, varscan2
- UNC119B | c.*2977A>C | 3'UTR (SNP) | VAF 31/69 reads (45%) | called by muse, mutect2, varscan2
- WNT7B | c.71+4462C>T | Intron (SNP) | VAF 7/33 reads (21%) | catalogued as rs1271791591; called by muse, mutect2, varscan2
- XKRX | chrX:100929232 del CAAAAACTAA | 5'Flank (DEL) | VAF 9/56 reads (16%) | called by mutect2, pindel, varscan2
- ZDHHC14 | c.*4802A>T | 3'UTR (SNP) | VAF 38/90 reads (42%) | called by muse, mutect2, varscan2
- ZNF487 | c.*438C>T | 3'UTR (SNP) | VAF 25/127 reads (20%) | called by muse, mutect2
- ZSCAN30 | c.-104+5089G>A | Intron (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
